Gene-level copy-number profile of tumor specimen TCGA-24-1563-01A from TCGA case TCGA-24-1563, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.5 years (24,274 days).
Specimen TCGA-24-1563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ebfb5ea7-457c-49f1-830b-d2ec9e10d930.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1563-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b73503a8-33ae-441f-92f4-88717c83e0cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,822; copy number 2: 36,730; copy number 3: 7,326; copy number 4: 1,189; copy number 5: 573; copy number 6: 178.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1563-01A-01D-0497-01): tumor purity 0.85, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 751 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:87,407,972–87,891,869, 14 genes, copy number 6 (within-gene range 3–6): CFAP206, AL049697.1, AL049697.2, AL049697.3, ST13P16, SLC35A1, RNU6-444P, RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1.
- chr8:98,904,603–145,066,685, 733 genes, copy number 5–6 (broad region; genes not listed).
- chr11:49,305,714–49,434,438, 4 genes, copy number 5: AC118942.1, TYRL, CBX3P8, AC135977.1.

Autosomal genes at a single copy (total copy number 1): 13,058. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
